Surgical pathology report (de-identified scan), TCGA case TCGA-GR-A4D5, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site University of Nebraska Medical Center (UNMC), specimen TCGA-GR-A4D5-01A (Primary Tumor).

[page 1 of 12]
Department of Pathology and Microbiology

Name:				Accession No:	
Hosp No:		Acct No:		Date Taken:	
DOB:		Age:		Date Received:	
Sex:	F			Submitted by:	
Loc:		Room:		Client:	

Surgical Pathology

Final Diagnosis:

- A LEFT LEVEL 2B LYMPH NODE, EXCISION: LYMPH NODE WITH REACTIVE HYPERPLASIA AND BENIGN SALIVARY GLAND TISSUE WITH NO DIAGNOSTIC PATHOLOGY.
- B RIGHT NECK LESION, BIOPSY: SKIN WITH DIFFUSE LARGE B-CELL LYMPHOMA, NONCLEAVED. (B-DLCL-NC)
- C LEFT DEEP LEVEL 2 LYMPH NODE, EXCISION: LYMPH NODE WITH DIFFUSE LARGE B-CELL LYMPHOMA, NONCLEAVED. (B-DLCL-NC)

ICD-O-3
lymphoma, diffuse,
large B-cell, NOS.
9680/3
Site: lymph node,
cervical
92012 RD. CT.0

Addendum

Addendum

has reviewed the case.

History:

These materials were examined by all those listed to establish the diagnosis with the signature being the responsible staff pathologist

[page 2 of 12]
Name: [REDACTED] D.O.B. [REDACTED] Sex: F Accession No: [REDACTED]
Submitted by: [REDACTED] Date Taken: [REDACTED] Hosp No: [REDACTED]

Surgical Pathology

The patient is a [REDACTED]-year-old female with a history of cervical lymphadenopathy and skin lesions.

Intraoperative Diagnosis:

Lymph node, level 2B, excision (FSA1 and touch prep): Lymphoid tissue present, pending additional workup. This was performed by Dr. [REDACTED] and reported to Dr. [REDACTED] over the phone by Dr. [REDACTED]

Source/Gross:

The specimens are received fresh in three containers labeled [REDACTED]

Part A is designated "left level 2B lymph node" and consists of a 0.9 x 0.7 x 0.4 cm lymph node. The specimen is bisected and entirely submitted for frozen section diagnosis in cryoblock FSA1. Following frozen section diagnosis, half of the specimen is sent for molecular diagnostic studies (one piece - 1.9 x 0.9 x 0.2 cm). The remainder of the specimen is entirely submitted in block A1 in B-plus for permanent sections (one piece - 1.9 x 0.9 x 0.2 cm).

Part B is designated "right skin lesion" and consists of a 1.6 x 0.9 cm ellipse of skin with attached subcutaneous tissue measuring 1.2 x 1.6 x 0.5 cm. The skin surface is white and unremarkable, no lesions are identified. Sectioning demonstrates an ill-defined pale area underlying the skin surface, measuring 0.9 x 0.5 x 1.0 cm.

The specimen is submitted as per the Lymphoma Study Group Protocol:

Touch preps are made - One.

Fixed in formalin for 24 hours - One piece, 1.4 x 0.9 x 0.4 cm, block B1.

Frozen in OCT for immunohistochemical studies - One piece, 1.1 x 0.5 x 0.5 cm.

Placed sterilely in medium for cytogenetics - One piece

Frozen in foil for molecular diagnostic studies - One piece, 0.9 x 0.6 x 0.5 cm.

Fixed in B-plus - one piece, 1.1 x 1.0 x 0.4 cm, block B2.

Placed in cytogenetic media for molecular research: One piece, 1.4 x 0.3 x 0.3 cm)

Part C is designated "left deep level 2 lymph node" and consists of a 4.3 x 1.7 x 1.4 cm lymph node candidate. Sectioning demonstrates a 2.7 x 1.8 x 0.8 cm tan-gray nodule. Adjacent to this larger nodule is a smaller nodule which measures 0.9 x 0.5 x 0.4 cm.

The entire specimen is submitted as per the Lymphoma Study Group Protocol:

Touch preps are made - Two.

Fixed in formalin for 24 hours - Two pieces, 2.1 x 1.4 x 0.3 cm and 1.4 x 0.9 x 0.3 cm, cassettes C1-C2.

Frozen in OCT for immunohistochemical studies - One piece, 1.8 x 0.9 x 0.3 cm.

Placed sterilely in medium for cytogenetics - One piece, 1.4 x 1.9 x 0.3 cm.

Frozen in foil for molecular diagnostic studies - One piece, 1.9 x 1.0 x 0.3 cm.

Fixed in B-plus - Two pieces, 1.9 x 1.4 x 0.3 cm and 2.0 x 1.4 x 0.3 cm, blocks C3-C4.

[page 3 of 12]
Name:

Submitted by:

D.O.B.

Date Taken:

Sex: F

Accession No:

Hosp No:

Surgical Pathology

The remainder of the specimen is entirely submitted in blocks C5-C7 for 24-hour formalin fixation

[page 4 of 12]
Name: [REDACTED] D.O.B. [REDACTED] Sex: F Accession No: [REDACTED]
Submitted by: [REDACTED] Date Taken: [REDACTED] Hosp No: [REDACTED]

Surgical Pathology

Gross dictated by: [REDACTED]

Microscopic:

IMMUNOPEROXIDASE REPORT

PARAFFIN TISSUE - The [REDACTED]

B-Cell Markers

T-Cell Markers

CD20(L26)
Kappa (ISH)
Lambda (ISH)
CD10

CD43(L60)
CD3
CD5

INTERPRETATION: The paraffin markers indicate a reactive phenotype.

The in-situ hybridization tests for kappa and lambda light chains were developed and the performance characteristics determined by [REDACTED] Immunoperoxidase Laboratory. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments (CLIA) as qualified to perform high complexity clinical laboratory testing.

PARAFFIN TISSUE - The [REDACTED]

B-Cell Markers

T-Cell Markers

Other Markers

CD20(L26)
CD79a
CD10

++ ✓
ND
- ✓

CD45RO(UCHL1)
CD43(L60)
CD3
CD5

ND
ND
-* ✓
- ✓

CD45(LCA)
CD30(Ber-H2)
CD15(Leu M1)
BCL-2
BCL-6
MUM1

+ ✓
+ (rare) ✓
- ✓
+ ✓
+ ✓
+ ✓

* = Done also on block B2

INTERPRETATION: The paraffin markers indicate a B-cell lymphoma, non-GCB phenotype.

[page 5 of 12]
Name:
Submitted by:

D.O.B.
Date Taken

Sex: F

Accession No:
Hosp No:

Surgical Pathology

[page 6 of 12]
Department of Pathology and Microbiology

Name:

Hosp No:

DOB:

Sex:

Loc:

Acct No:

Age:

Room:

Accession No:

Date Taken:

Date Received:

Submitted by:

Client:

Surgical Pathology
Addendum Report

Addendum

has reviewed the case.

Signed:

These materials were examined by all those listed to establish the diagnosis with the signature being the responsible staff pathologist.

[page 7 of 12]
ANATOMIC PATHOLOGY
INTRADEPARTMENTAL CONSULTATION FORM

To: [REDACTED] From: [REDACTED]

Case #: [REDACTED] Slides: [REDACTED]

Source of Specimen: SKIN & LN (BEC)

Age: [REDACTED] Sex: F

Prior Diagnoses: [REDACTED]

Relevant lab x-ray physical findings: [REDACTED]

☒ Signature ☐ Difficult Case

Specific question(s) for consultant:

B. DLCL - NC

Consultant's impression/diagnosis:

[REDACTED]

Prior Diagnosis:

Relevant lab x-ray physical

☒ Signature

Specific question(s) for consultant:

What normal to Specimen A ??
See my suggested corrections.

[page 8 of 12]
SURGICAL PATHOLOGY
SPECIMEN REQUEST FORM

PATIENT INFORMATION

NAME: _____

MEDICAL I

DATE OF B

SEX: ☐ Male☐ Female

(AFFIX PATIENT LABEL HERE IF AVAILABLE)

CLINICAL HISTORY, PRE OPERATIVE DIAGNOSIS, POST OPERATIVE DIAGNOSIS, OR OTHER PERTINENT LABORATORY FINDINGS:

Cervical lymphadenopathy Skin lesions

POSSIBLE DUPLICATE
PATIENT

SPECIAL REQUEST: (Please specify)

* For lymphoma work up

ORDERING PROVIDER

REFERRING PHYSICIAN:

DATE/TIME SPECIMEN COLLECTION:

SPECIMEN SOURCE:

* Axillary 2B lymph Node

FROZEN SECTION:

YES ☒

NO

OR NO

EXT

FROZEN SECTION DIAGNOSIS:

FSA, & TP

Lymphoid tissue present
pending ~~lymph~~ additional
work up.

PATHOLOGIST SIGNATURE:

REPORT TO:

TIME RECEIVED:

TIME REPORTED:

CREW CHECK

- ☒ Patient's ID Check
- ☒ Site Verification
- ☒ Label Verification
- ☒ Form Complete
- ☒ Specimen and Form Bagged

LAB USE ONLY

[page 9 of 12]
**SURGICAL PATHOLOGY
SPECIMEN REQUEST FORM****PATIENT INFORMATION**

NAME: _____
Last
MEDICAL RECORD NO. _____
DATE OF BIRTH: _____
Month Day Year
SEX: ☐ Male ☐ Female

(AFFIX PATIENT LABEL HERE IF AVAILABLE)

CLINICAL HISTORY, PRE OPERATIVE DIAGNOSIS, POST OPERATIVE DIAGNOSIS, OR OTHER PERTINENT LABORATORY FINDINGS:

*Cervical lymphadenopathy
skin lesions*

SPECIAL REQUEST: (Please specify)

For lymphoma Work Up

ORDERING PROVIDER: _____

FROZEN SECTION: YES ☐ NO ☒

REFERRING PHYSICIAN: _____

OR NO _____ EXT _____

DATE/TIME SPECIMEN COLLECTION _____

FROZEN SECTION DIAGNOSIS: _____

SPECIMEN SOURCE:

Right Skin Neck

PATHOLOGIST SIGNATURE: _____

REPORT TO: _____

TIME RECEIVED: _____

TIME REPORTED: _____

CREW CHECKLIST

- ☒ Patient's ID Check
- ☒ Site Verification
- ☒ Label Verification
- ☒ Form Complete
- ☒ Specimen and Form Bagged

LAB USE ONLY

[page 10 of 12]
SURGICAL PATHOLOGY
SPECIMEN REQUEST FORM

PATIENT INFORMATION

NAME MMED DATE Month Day YearSEX: ☐ Male☐ Female

(AFFIX PATIENT LABEL HERE IF AVAILABLE)

CLINICAL HISTORY, PRE OPERATIVE DIAGNOSIS, POST OPERATIVE DIAGNOSIS, OR OTHER PERTINENT LABORATORY FINDINGS:

Cervical lymphadenopathy
Skin lesions

SPECIAL REQUEST: (Please specify)

* For lymphoma Study

ORDERING PROVIDER: REFERRING PHYSICIAN: DATE/TIME SPECIMEN COLLECTION:

SPECIMEN SOURCE:

③ Left Deep level 2 lymph Node

- _____
- _____
- _____
- _____
- _____
- _____
- _____
- _____

FROZEN SECTION:

YES ☐NO ☒OR NO. EXT.

FROZEN SECTION DIAGNOSIS:

PATHOLOGIST SIGNATURE: _____

REPORT TO: _____

TIME RECEIVED: _____

TIME REPORTED: _____

CREW CHECKLIST

- ☒ Patient's ID Check
- ☒ Site Verification
- ☒ Label Verification
- ☒ Form Complete
- ☒ Specimen and Form Bagged

Nursing Signature

LAB USE ONLY

[page 11 of 12]
Surgical #:

Outside Surgical #:

Date: _____

☐ Referral Immunostains Reviewed AND / OR ☒ Done at

PARAFFIN TISSUE - Outside Surgical #

Other Markets

CD45(LCA)

CD30(Ber-H2)

CD15(Leu M1)

BCL-2

BCU-6

Cyclin D1

ALK

BMLA

Ki-67

CD21

EBERs

I = Indeterminate

If in situ hybridization, please check as appropriate:

ASR: ☐ Kappa/Lambda ☐ EBV ☐ Kappa/Lambda and EBV

Quick Text: ASRKL ASREBY ASRKLBBY

INTERPRETATION (Circle):

1. Monoclonal B-cell lymphoma (IgG, IgA, IgM, IgD, kappa, lambda).
2. B-cell lymphoma, surface Ig negative.
3. Consistent with peripheral T-cell lymphoma, (helper/inducer, cytotoxic/suppressor) cell type.
4. Consistent with Hodgkin's disease, (classical type, lymphocyte-predominant type).
5. The paraffin markets indicate a (B-cell, T-cell, null) phenotypes.
6. Specify: → cutaneous phenotype

PATHOLOGIST:

[page 12 of 12]
IMMUNOPEROXIDASE REPORT

Patient: _____ Surgical #: _____
LR# _____ Outside Surgical #: _____
Date: _____

☐ Referral Immunostatus Reviewed AND / OR ☒ Done at _____

PARAFFIN TISSUE - Outside Surgical # _____

B-Cell Markers

CD20(L26) + *
CD79a _____
Kappa (ISH) _____
Lambda (ISH) _____
CD22 _____
CD10 _____

T-Cell Markers

CD45RO(UCHL1) _____
CD43(L60) _____
CD3 _____ *
CD5 _____
CD2 _____
CD4 _____
CD7 _____
CD8 _____

Other Markers

CD45(LCA) +
CD30(Ber-H2) + (weak)
CD15(Leu M1) _____
BCL-2 + *
BCL-6 +
Cyclin D1 _____
ALK _____
EMA _____
Ki-67 _____
CD21 _____
EBERs _____

mem +

* Done also on block B2

I = Indeterminate

If in situ hybridization, please check as appropriate:

ASR: ☐ Kappa/Lambda ☐ EBV
Ouk Test: ASREL ASREBV

☐ Kappa/Lambda and EBV
ASRKLBBV

INTERPRETATION (Circle):

- Monoclonal B-cell lymphoma (IgG, IgA, IgM, IgD, kappa, lambda).
- B-cell lymphoma, surface Ig negative.
- Consistent with peripheral T-cell lymphoma, (helper/inducer, cytotoxic/suppressor) cell type.
- Consistent with Hodgkin's disease, (classical type, lymphocyte-predominant type).
- The paraffin markers indicate a B-cell, T-cell, null) phenotype.
- Specify: rel, non GCB phenotype

PATHOLOGIST: _____

Source: NCI Genomic Data Commons file db1b1f7e-1b3e-48a2-9135-6fdca9f134e4 (TCGA-GR-A4D5.97EAEC1D-1C5A-4FE8-8D2B-80DD433DB18C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).